Surgical pathology report (de-identified scan), TCGA case TCGA-AH-6897, project TCGA-READ (Rectum Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-AH-6897-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology

Histopathological Examination

Pre-Op Diagnosis : Sigmoid Colon Cancer
Order Physician :
Specimens : Colon Segment, sigmoid upper rectum
Frozen Diagnosis :

Report : GROSS EXAMINATION:

The specimen is received fresh in a container labeled with the name of the patient and identified as colon segment, sigmoid, upper rectum.

Length: 15 cm

Circumference: Up to 7.3 cm

Margins: Stapled

Serosa: Smooth and glistening

Mesorectum: Incomplete

Mass:

Size: 5.3 x 4.2 x 1.4 cm

Type: Infiltrative with raised edges

Region: Distal segment

Distance from distal margin: 4.5 cm

Circumference: Approximately 60%

Depth of Invasion: 0.3 cm

Distance from Radial Margin: 3 cm

Block Summary: 1-2, mass with overlying inked serosal edge (black ink); 3-4, additional sections of mass with adjacent normal bowel wall; 5, radial margin; 6, distal margin; 7, proximal margin; 8, lymph nodes; 9-12, additional sections of mesocolon and mesorectum submitted post alcoholic formalin fixation

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

Colon, sigmoid/upper rectum, segmental resection:

- Invasive adenocarcinoma, moderately differentiated extending into muscularis propria (see cancer case summary checklist).
- Margins are free of tumor.
- Benign lymph nodes, negative for metastatic adenocarcinoma

[page 2 of 3]
(0/14).

[T-59300 M-81403 153.9 P3-44090]

COLON AND RECTUM:

SPECIMEN: Sigmoid colon and rectum.

PROCEDURE: Rectal/rectosigmoid colon (lower anterior resection).

TUMOR SITE: Rectosigmoid.

TUMOR SIZE: 5.3 x 4.2 x 1.4 cm

MACROSCOPIC TUMOR PERFORATION: Not identified.

HISTOLOGIC TYPE: Adenocarcinoma.

HISTOLOGIC GRADE: Low-grade (well differentiated and moderately differentiated).

HISTOLOGIC FEATURES SUGGESTIVE OF MICROSATELLITE

INSTABILITY: Not identified. MICROSCOPIC TUMOR EXTENSION: Tumor invades muscularis propria.

MARGINS:

Proximal margin uninvolved by invasive carcinoma.

Distal margin uninvolved by invasive carcinoma.

Circumferential (radial or mesenteric) margin uninvolved by invasive carcinoma.

Distance of tumor from closest margin: 3 cm, radial margin.

TREATMENT EFFECT: No prior treatment.

LYMPH-VASCULAR INVASION: Not identified.

PERINEURAL INVASION: Not identified.

TUMOR DEPOSITS: Not identified.

PATHOLOGIC STAGING (pTNM):

Primary Tumor (pT): pT2: Tumor invades muscularis propria.

Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis.

Number examined: 14

Number involved: 0

Distant Metastasis (pM): N/A

ADDITIONAL PATHOLOGIC FINDINGS: None identified.

ANCILLARY STUDIES: None performed.

SUMMARY OF PATHOLOGIC STAGING: pT2N0

Comment: The preliminary findings have been discussed with [REDACTED] Intradepartmental consultation obtained.

[REDACTED]

Electronically Signed by:

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

[page 3 of 3]
THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Source: NCI Genomic Data Commons file 39962782-4393-442e-8f05-d0168faed806 (TCGA-AH-6897.8BEFF8A6-B443-4073-9FAA-552C57E075D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).